Gene-level copy-number profile of tumor specimen MP2PRT-PAVEDY-TMP1-A from MP2PRT case MP2PRT-PAVEDY, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.6 years (2,793 days).
Specimen MP2PRT-PAVEDY-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1504ae52-fec4-4641-921e-7fcb860c642a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAVEDY-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,733 have no estimate.
https://portal.gdc.cancer.gov/files/b5059620-c533-4d49-ac35-ae718b012f48

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 139; copy number 1: 528; copy number 2: 49,922; copy number 3: 2,973; copy number 4: 4,500; copy number 5: 823; copy number 6: 2; copy number 18: 3.

Homozygous deletions (total copy number 0; autosomes only): 139 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,170,775–89,192,752, 4 genes (within-gene range 0–2): IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25.
- chr2:89,234,174–89,275,787, 6 genes (within-gene range 0–2): IGKV2-29, IGKV2-30, IGKV3-31, IGKV1-32, IGKV1-33, IGKV3-34.
- chr2:90,220,727–90,221,384, 1 gene: IGKV1D-8.
- chr2:113,325,372–113,425,548, 1 gene (within-gene range 0–2): AC016745.1.
- chr2:113,432,600–113,436,042, 1 gene: AC016745.2.
- chr7:38,253,380–38,296,233, 8 genes (within-gene range 0–1): TRGJ2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB.
- chr14:105,672,308–106,481,706, 116 genes (within-gene range 0–4) (broad region; genes not listed).
- chr14:106,531,141–106,538,344, 2 genes (within-gene range 0–4): IGHVIII-47-1, IGHV3-48.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 828 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–143,500,512, 5 genes, copy number 6–18: AC239859.5, RNA5SP533, AC239859.3, AC239859.2, LINC02799.
- chr15:19,878,555–21,946,641, 105 genes, copy number 5 (broad region; genes not listed).
- chr21:13,305,152–46,691,226, 718 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 528. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
